Somatic mutation profile of tumor specimen TCGA-KL-8334-01A (aliquot TCGA-KL-8334-01A-11D-2310-10) from TCGA case TCGA-KL-8334, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 37.2 years (13,602 days).
Specimen TCGA-KL-8334-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b78051-018d-4027-a32e-c4e6dc3e050e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8334-11A (Solid Tissue Normal), aliquot TCGA-KL-8334-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0320794c-f008-45e1-a410-a16f4aa32afe

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as rs183234182; called by muse, mutect2, varscan2
- PNISR | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100984337; called by muse, mutect2
- TBC1D24 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761934676; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTS7 | c.2616del p.K873Sfs*84 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- HOXB4 | c.506A>T p.Y169F | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.4260A>T p.K1420N | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM11 | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- USP9X | c.7384dup p.S2462Kfs*3 | Frame Shift Ins (INS) | VAF 68/136 reads (50%) | called by mutect2, pindel, varscan2
- ANKS1B | c.96C>T p.G32= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- DOT1L | c.951C>T p.I317= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs778762925, COSV67109785; called by muse, mutect2, varscan2
- TRAPPC8 | c.216A>G p.V72= | Silent (SNP) | VAF 86/203 reads (42%) | called by muse, mutect2, varscan2
